Somatic mutation profile of tumor specimen ALCH-B1T1-TTP1-A (aliquot ALCH-B1T1-TTP1-A-2-0-D-A76I-36) from ALCHEMIST case ALCH-B1T1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.3 years (24,944 days).
Specimen ALCH-B1T1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 998f2941-aa8d-4bfe-91f8-e7418815bc81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1T1-NB1-A (Blood Derived Normal), aliquot ALCH-B1T1-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4f26240-0693-4741-9783-5bc3dfe8323e

The open-access MAF lists 66 somatic variants for this specimen: 47 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 11, Frame Shift Del 4, RNA 4, Intron 3, In Frame Del 1, Splice Site 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 891/1483 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 84/181 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.046); catalogued as rs930779979, COSV61005740; called by muse, mutect2, varscan2
- BSND | c.675A>T p.Q225H | Missense Mutation (SNP) | VAF 32/456 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.117); catalogued as rs202112062; called by muse, mutect2
- C16orf92 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 55/439 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs370643656, COSV54228068; called by muse, mutect2, varscan2
- CHST13 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.56); catalogued as rs1289154843, COSV60042041; called by muse, mutect2, varscan2
- CLEC3A | c.437C>T p.T146M (on ENST00000651443; = p.T137M on NM_005752.6) | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as rs1045384121, COSV55222095, COSV55224097; called by muse, mutect2, varscan2
- FAM47B | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV61453403; called by muse, mutect2
- HOXC4 | c.525del p.H176Ifs*6 | Frame Shift Del (DEL) | VAF 38/250 reads (15%) | catalogued as COSV57700080; called by mutect2, pindel, varscan2
- INTS3 | c.1583A>G p.Y528C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.417); catalogued as rs146465214; called by muse, mutect2, varscan2
- ITGAM | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.245); catalogued as rs903204583; called by muse, mutect2, varscan2
- KLHDC9 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749947043; called by muse, mutect2
- MAGEB6 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.181); catalogued as rs375799757, COSV66872296; called by muse, mutect2
- MEN1 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1555166469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.031); catalogued as rs371265439; called by muse, mutect2, varscan2
- PCDHA13 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs1554181269, COSV56504468; called by muse, mutect2, varscan2
- PCDHA2 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 90/399 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs547468977, COSV65364688; called by muse, mutect2, varscan2
- PHC2 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 87/402 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs61760981; called by muse, mutect2, varscan2
- PLCH2 | c.4103G>A p.R1368Q | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs570757016, COSV53941287, COSV99616770; called by muse, mutect2, varscan2
- RNF41 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as rs1251875884; called by muse, mutect2, varscan2
- SLC34A2 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV65943275; called by muse, mutect2, varscan2
- SLC35F1 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 52/505 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs371673898, COSV100837525; called by muse, mutect2
- TCERG1L | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs777213874; called by muse, mutect2
- WDR93 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249418248; called by muse, varscan2
- ZNF440 | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV58372839; called by muse, varscan2
- ATP6AP1 | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 85/1058 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC138 | c.706G>T p.V236F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CHM | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- CLEC18B | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 43/360 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLRN2 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DRC3 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAM200B | c.1215del p.H406Tfs*21 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by pindel, varscan2
- FLG | c.9722G>A p.G3241E | Missense Mutation (SNP) | VAF 82/557 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR62 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- HMCN2 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ICE1 | c.1436T>C p.L479S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, varscan2
- MAGEC2 | c.788A>G p.E263G | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- MN1 | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTA3 | c.1735del p.Y579Tfs*153 (on ENST00000405094 / NM_001330442.2; = p.Y522Tfs*153 on NM_001282755.1) | Frame Shift Del (DEL) | VAF 44/99 reads (44%) | called by mutect2, pindel, varscan2
- NBPF15 | c.1990_1995del p.M664_G665del | In Frame Del (DEL) | VAF 22/132 reads (17%) | called by pindel, varscan2
- NDUFA4 | c.43-9_44del p.X15_splice | Splice Site (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- PACRGL | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PREX1 | c.1400G>A p.G467D | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TRGV2 | c.114A>T p.E38D | Missense Mutation (SNP) | VAF 283/498 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VPS13B | c.9796C>T p.L3266F | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, varscan2
- ZNF319 | c.1194_1195del p.F399Qfs*10 | Frame Shift Del (DEL) | VAF 35/270 reads (13%) | called by pindel, varscan2
- ZNF879 | c.1602T>G p.H534Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRMPD3 | c.2664C>T p.G888= | Silent (SNP) | VAF 61/254 reads (24%) | catalogued as rs747060737, COSV52189187; called by muse, mutect2, varscan2
- MSRB2 | c.21G>A p.L7= | Silent (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- P2RX3 | c.15C>T p.S5= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs748037477, COSV53478229; called by muse, mutect2, varscan2
- PCDH19 | c.732G>A p.A244= | Silent (SNP) | VAF 40/298 reads (13%) | catalogued as rs760603190; called by muse, mutect2, varscan2
- PDE6B | c.609C>T p.S203= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as rs762366124; called by muse, mutect2, varscan2
- S100A7A | c.249C>T p.A83= | Silent (SNP) | VAF 22/223 reads (10%) | catalogued as rs770816797, COSV61330083; called by muse, mutect2, varscan2
- SIPA1 | c.2577C>G p.L859= | Silent (SNP) | VAF 41/350 reads (12%) | called by muse, mutect2, varscan2
- SLC16A5 | c.546C>T p.C182= | Silent (SNP) | VAF 38/223 reads (17%) | catalogued as rs747676766; called by muse, mutect2, varscan2
- SLIT3 | c.3039C>T p.D1013= | Silent (SNP) | VAF 58/443 reads (13%) | catalogued as rs79266600; called by muse, mutect2, varscan2
- ZMYM4 | c.3229C>T p.L1077= | Silent (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- ZNF804B | c.3054A>G p.A1018= | Silent (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- AC024940.1 | n.5162G>C | RNA (SNP) | VAF 14/128 reads (11%) | called by muse, varscan2
- AC116351.1 | n.1346del | RNA (DEL) | VAF 4/22 reads (18%) | called by pindel, varscan2
- AC244197.3 | c.-1954G>T | 5'UTR (SNP) | VAF 12/79 reads (15%) | catalogued as rs1356691091; called by muse, mutect2, varscan2
- ADAM21P1 | n.1805C>A | RNA (SNP) | VAF 19/170 reads (11%) | called by muse, mutect2, varscan2
- LINC02649 | n.47C>A | RNA (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- RNASET2 | c.87-45_87-42del | Intron (DEL) | VAF 26/168 reads (15%) | called by mutect2, pindel, varscan2
- SH3BP5L | c.376-141T>A | Intron (SNP) | VAF 21/262 reads (8%) | called by muse, mutect2
- UTRN | c.7479+6293G>A | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
